Somatic mutation profile of tumor specimen C3N-00223-01 (aliquot CPT0111300009) from CPTAC case C3N-00223, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 69.5 years (25,368 days).
Specimen C3N-00223-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a324b797-ee46-4b89-a810-77fb4d957996.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00223-31 (Blood Derived Normal), aliquot CPT0111560002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14b8beda-6594-4933-96f1-ebd14b805f40

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, 3'UTR 3, Intron 2, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 59/423 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- CACNA1I | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776635350; called by muse, mutect2, varscan2
- CALCOCO1 | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1282288769, COSV50422434; called by muse, mutect2
- CASP8AP2 | c.5822G>A p.C1941Y | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52748135; called by muse, mutect2, varscan2
- COL14A1 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52851310, COSV52854219; called by muse, mutect2, varscan2
- DLL3 | c.523C>A p.R175S | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs1169753159; called by muse, mutect2, varscan2
- GCN1 | c.3780T>A p.F1260L | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.295); catalogued as rs777271401; called by muse, mutect2, varscan2
- OR6F1 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0.084); catalogued as COSV100129235; called by muse, mutect2
- PCDHGA1 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); catalogued as rs577475018, COSV65299631; called by muse, mutect2, varscan2
- RBM10 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs200120271; called by muse, mutect2, varscan2
- TGFBR1 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 15/294 reads (5%) | catalogued as COSV66627240; called by muse, mutect2
- APOL1 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 29/203 reads (14%) | called by muse, mutect2, varscan2
- ATP8B4 | c.2396T>C p.V799A | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DPM3 | c.152G>T p.C51F (on ENST00000341298; = p.C81F on NM_018973.3) | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- EGFR | c.2239T>G p.L747V | Missense Mutation (SNP) | VAF 58/364 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ESAM | c.399dup p.Q134Tfs*5 | Frame Shift Ins (INS) | VAF 29/230 reads (13%) | called by mutect2, pindel, varscan2
- GOLGA1 | c.824T>G p.L275R | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- HYPK | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JPH3 | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); called by muse, mutect2
- MDN1 | c.1312T>G p.F438V | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MFSD11 | c.122G>C p.R41T | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- NCOA2 | c.3059dup p.P1021Tfs*4 | Frame Shift Ins (INS) | VAF 38/177 reads (21%) | called by mutect2, pindel, varscan2
- NPAP1 | c.1885C>A p.H629N | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PSMA8 | c.691A>C p.K231Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPRZ1 | c.6866A>C p.E2289A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RNF112 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- STX1B | c.105+1G>A p.X35_splice | Splice Site (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- TEX26 | c.308A>T p.N103I | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UVSSA | c.2012_2013del p.R671Hfs*34 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | called by mutect2, pindel, varscan2
- WAC | c.1036del p.S346Lfs*41 | Frame Shift Del (DEL) | VAF 50/353 reads (14%) | called by mutect2, pindel, varscan2
- ZNF226 | c.624G>C p.W208C | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM20 | c.2178A>T p.G726= | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, varscan2
- ARHGAP35 | c.2517A>G p.S839= | Silent (SNP) | VAF 46/280 reads (16%) | called by muse, mutect2, varscan2
- ARID5B | c.3525A>G p.P1175= | Silent (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2
- LNPEP | c.2121T>C p.D707= | Silent (SNP) | VAF 16/136 reads (12%) | called by muse, varscan2
- PPP2R1A | c.1470C>T p.S490= | Silent (SNP) | VAF 46/250 reads (18%) | catalogued as rs187141962, COSV59046173; called by muse, mutect2, varscan2
- STAP2 | c.735G>T p.L245= | Silent (SNP) | VAF 49/271 reads (18%) | catalogued as COSV55695634; called by muse, mutect2, varscan2
- THAP5 | c.849C>A p.P283= (on ENST00000415914 / NM_001130475.3; = p.P241= on NM_182529.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- ARX | c.*106C>T | 3'UTR (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- EIF4A2 | c.909+84C>T | Intron (SNP) | VAF 30/232 reads (13%) | catalogued as COSV56218441; called by muse, mutect2, varscan2
- GLRXP3 | n.137T>A | RNA (SNP) | VAF 12/385 reads (3%) | called by muse, mutect2
- IL6 | c.19+56G>A | Intron (SNP) | VAF 14/329 reads (4%) | called by muse, mutect2
- POR | c.*135G>A | 3'UTR (SNP) | VAF 29/392 reads (7%) | catalogued as rs372930296; called by muse, mutect2
- ZNF672 | c.*206T>G | 3'UTR (SNP) | VAF 7/152 reads (5%) | called by muse, mutect2
